TARGET case TARGET-15-SJMPAL040032 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/07a3dbde-325c-42bb-857e-dbda52a52119

Demographics
Sex at birth: male; Age at index: 0 years; Vital status: Dead; Days to death: 436 days (1.2 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.4 years (135 days); Year of diagnosis: 1995; Days to last follow up: 436 days (1.2 years).

Follow-up (1 entry)
- Days to follow up: 436 days (1.2 years); Event-free: no event (relapse, second malignancy or death) recorded through day 436; Year of follow up: 1996.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 1500 ×10³/µL.

Biospecimens (5 samples)
- Samples TARGET-15-SJMPAL040032-09A, TARGET-15-SJMPAL040032-09A.1, TARGET-15-SJMPAL040032-09A.3 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL040032-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-15-SJMPAL040032-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 436
- Protocol: DCOG
- WBC at Diagnosis: 1500
- Initial Therapy: ALL
- WHO ALAL Classification: MLL
- WHO Dx: MLL
